TCGA case TCGA-F7-8489 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Floor of mouth; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/513b1a26-8f1b-49a0-8957-de10930e6c98

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C04.9; Tissue or organ of origin: Floor of mouth, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Midline; Classification of tumor: primary; Age at diagnosis: 48.9 years (17,873 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage II; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 658 days (1.8 years).
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes tested: 8; Lymphatic invasion present: No; Margin status: Indeterminate; Perineural invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 14 days; Disease response: Tumor Free.
- Days to follow up: 658 days (1.8 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 300; Tobacco smoking onset year: 1992.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-F7-8489-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.8; Intermediate dimension: 1.1; Shortest dimension: 0.3.
  Slide TCGA-F7-8489-01A-02-BS2: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-F7-8489-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-F7-8489-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Close; Lymphovascular invasion: No; Tobacco smoking history indicator: 2; Alcohol history documented: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 658 days; disease-specific survival: no event (censored), 658 days; disease-free interval: no event (censored), 658 days; progression-free interval: no event (censored), 658 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-F7-8489-01A-31D-2390-01): tumor purity 0.27, ploidy 1.96, whole-genome doublings 0.
